TCGA case TCGA-15-1444 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Mayo Clinic - Rochester. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4c42dc4e-66b7-40bf-9fbe-b92543248198

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 21 years; Vital status: Dead; Days to death: 1,537 days (4.2 years).

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 21.4 years (7,827 days); Year of diagnosis: 2004; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 6 days; Days to treatment end: 78 days; Treatment dose: 6,000 cGy; Treatment outcome: Complete Response; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carmustine + Irinotecan Hydrochloride; Days to treatment start: 38 days; Days to treatment end: 72 days; Clinical trial indicator: Yes.
2. Progression of diagnosis 1 (Glioblastoma). Age at diagnosis: 25.7 years (9,377 days); Days to diagnosis: 1,550 days (4.2 years); Prior treatment: Yes.

Follow-up (2 entries)
- Days to follow up: 1,537 days (4.2 years); Disease response: With Tumor.
- Day 1,550 (post initial treatment): Progression or recurrence: Yes; Days to progression: 1,550 days (4.2 years); Days to recurrence: 1,550 days (4.2 years).

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-15-1444-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.8; Intermediate dimension: 1.1; Shortest dimension: 0.5.
  Slide TCGA-15-1444-01A-02-BS2: Section location: Top; Percent tumor cells: 20; Percent tumor nuclei: 40; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 80.
- Sample TCGA-15-1444-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-15-1444-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Glioblastoma Multiforme (GBM); History lgg diagnosis of brain tissue: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Treatment outcome first course: Complete Remission/Response.
- Drug treatment 1: Pharmaceutical therapy drug name: Bcnu.
- Drug treatment 2: Pharmaceutical therapy drug name: CPT-11.

GDC annotations on this case (curator notes; quoted as recorded):
- Pathology outside specification: Pathology Results off Spec.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,537 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,537 days; disease-free interval: event (new tumor event after initially disease-free), 1,550 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,550 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-15-1444-01A-02D-1694-01): tumor purity 0.6, ploidy 1.92, whole-genome doublings 0.
